Gene-level copy-number profile of tumor specimen TCGA-AL-3466-01A from TCGA case TCGA-AL-3466, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.6 years (15,181 days).
Specimen TCGA-AL-3466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.2e0b897d-1dac-44fc-8647-a00a1cde470b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AL-3466-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3efac49f-b884-4e27-9be3-c4d5354afd49

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 1,300; copy number 2: 11,749; copy number 3: 25,252; copy number 4: 7,740; copy number 5: 5,328; copy number 6: 6,467; copy number 7: 40; copy number 8: 60; copy number 9: 720; copy number 10: 643; copy number 11: 299; copy number 13: 181.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AL-3466-01A-01D-1190-01): tumor purity 0.64, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr9:21,638,285–24,088,051, 34 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,943 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–240,612,155, 40 genes, copy number 7: AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4.
- chr5:93,617,725–94,111,699, 1 gene, copy number 8 (within-gene range 6–8): FAM172A.
- chr5:93,860,669–97,437,217, 59 genes, copy number 8 (within-gene range 6–8): AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2, AC104123.1, AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2, PCSK1, CAST, AC020900.1, ERAP1, AC008906.1, AC008906.2, AC009126.1, ERAP2, LNPEP, AC008850.1, Y_RNA, SETP22, LIX1-AS1, LIX1, RIOK2, RNU1-73P, AC008883.3, AC008883.1, AC008883.2.
- chr5:151,595,264–181,342,213, 555 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr17:35,918,066–43,032,041, 378 genes, copy number 10–11 (within-gene range 4–11) (broad region; genes not listed).
- chr17:43,079,302–43,079,780, 1 gene, copy number 11: RPL21P4.
- chr17:53,276,760–54,365,634, 1 gene, copy number 9 (within-gene range 5–9): AC034268.2.
- chr17:53,681,630–83,095,122, 908 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
